Somatic mutation profile of tumor specimen TCGA-AL-3473-01A (aliquot TCGA-AL-3473-01A-01D-1252-08) from TCGA case TCGA-AL-3473, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 55.0 years (20,104 days).
Specimen TCGA-AL-3473-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21965229-07f0-4e13-9036-3e5d000ba604.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AL-3473-10A (Blood Derived Normal), aliquot TCGA-AL-3473-10A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bad086c4-470a-4d7d-b153-d0bacc747e55

The open-access MAF lists 51 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Del 4, Frame Shift Ins 2, Nonsense Mutation 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APLP1 | c.584T>A p.L195* | Nonsense Mutation (SNP) | VAF 50/313 reads (16%) | catalogued as COSV55703796; called by muse, mutect2, varscan2
- BIRC3 | c.1442T>G p.V481G | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV54817267; called by muse, mutect2, varscan2
- CD27 | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56950244; called by muse, mutect2, varscan2
- COL4A6 | c.1401A>C p.K467N | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV57868149; called by muse, mutect2, varscan2
- CSE1L | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.13); catalogued as COSV53702347; called by muse, mutect2, varscan2
- CUEDC2 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56523202; called by muse, mutect2, varscan2
- DNAH3 | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.607); catalogued as rs577456196, COSV54525760, COSV54531831, COSV54546125; called by muse, mutect2, varscan2
- FBXO40 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57524436; called by muse, mutect2, varscan2
- HERPUD2 | c.722C>A p.P241Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV60945405; called by muse, varscan2
- KIF1B | c.1336T>A p.C446S (on ENST00000377086 / NM_001365952.1; = p.C400S on NM_015074.3) | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV55809635; called by muse, mutect2, varscan2
- KIZ | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs746047414, COSV55685482; called by muse, mutect2
- KNSTRN | c.948G>T p.M316I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV51105900; called by muse, mutect2, varscan2
- LAMA2 | c.4486G>A p.A1496T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV70341839, COSV70348832; called by muse, mutect2, varscan2
- LRP2 | c.11023G>A p.A3675T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.231); catalogued as COSV55556323; called by muse, mutect2
- ME2 | c.417C>G p.D139E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV58423460; called by muse, mutect2, varscan2
- METTL17 | c.1113G>T p.M371I | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV53869758; called by muse, mutect2, varscan2
- METTL17 | c.1114G>T p.V372L | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV53869766; called by muse, mutect2, varscan2
- NID2 | c.2851T>G p.Y951D | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV53497237; called by muse, mutect2, varscan2
- NOD1 | c.2651T>C p.V884A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56112849; called by muse, mutect2, varscan2
- OXSM | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.372); catalogued as COSV55001730; called by muse, mutect2, varscan2
- PEX19 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs745665641, COSV63619639; called by muse, mutect2, varscan2
- PKNOX2 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53546947; called by muse, mutect2, varscan2
- PROS1 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.207); catalogued as rs761924988, COSV62398650; called by muse, mutect2, varscan2
- PSMC3IP | c.321C>A p.C107* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as rs1350206749, COSV53817387; called by muse, mutect2
- SNX15 | c.263T>G p.F88C | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57247169; called by muse, mutect2, varscan2
- SOX5 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV58631765; called by muse, mutect2, varscan2
- SPHKAP | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV60881452; called by muse, mutect2, varscan2
- SRGAP1 | c.146T>A p.L49Q | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61898742; called by muse, mutect2, varscan2
- TMEM106A | c.214C>T p.L72= | Splice Region (SNP) | VAF 14/145 reads (10%) | catalogued as COSV57832828; called by muse, varscan2
- TMEM107 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746705243, COSV57101434; called by muse, mutect2, varscan2
- VHL | c.349dup p.W117Lfs*15 | Frame Shift Ins (INS) | VAF 77/446 reads (17%) | catalogued as COSV56547585; called by mutect2, pindel, varscan2
- WDR35 | c.553A>T p.N185Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as COSV55603261; called by muse, mutect2, varscan2
- WDR62 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs750547223, COSV54331738, COSV99543709; called by muse, mutect2, varscan2
- ZNF512B | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 60/383 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs770288716, COSV53871660; called by muse, mutect2, varscan2
- ZNF585B | c.367A>T p.I123F | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs1018989031, COSV57215831; called by muse, mutect2, varscan2
- BAP1 | c.1272del p.K425Sfs*5 | Frame Shift Del (DEL) | VAF 57/316 reads (18%) | called by mutect2, pindel, varscan2
- CCAR2 | c.1857del p.L620Ffs*36 | Frame Shift Del (DEL) | VAF 86/643 reads (13%) | called by mutect2, pindel, varscan2
- MUC2 | c.2948G>A p.G983E | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- PEX13 | c.1042dup p.V348Gfs*15 | Frame Shift Ins (INS) | VAF 8/79 reads (10%) | called by mutect2, pindel, varscan2
- PITRM1 | c.1329del p.F443Lfs*3 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- SLC25A42 | c.902del p.I301Tfs*22 | Frame Shift Del (DEL) | VAF 20/187 reads (11%) | called by mutect2, pindel, varscan2
- EPC1 | c.2127T>C p.H709= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV53926272; called by muse, mutect2, varscan2
- GPBP1 | c.525T>A p.I175= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV53311943; called by muse, mutect2, varscan2
- LRIG2 | c.2358C>A p.S786= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV63162360; called by muse, mutect2, varscan2
- PCDHA4 | c.1938C>T p.R646= | Silent (SNP) | VAF 45/321 reads (14%) | catalogued as COSV63542353; called by muse, mutect2, varscan2
- PTGFR | c.759G>A p.A253= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs746863911, COSV66115064; called by muse, mutect2, varscan2
- RAB27A | c.426A>T p.V142= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV61016017; called by muse, mutect2, varscan2
- SCMH1 | c.1578C>T p.H526= (on ENST00000326197 / NM_001031694.2; = p.H479= on NM_012236.4) | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as rs780882573, COSV58236000; called by muse, mutect2, varscan2
- WASHC2C | c.2550G>A p.K850= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1374154110; called by mutect2, varscan2
- ZNF512B | c.129G>T p.P43= | Silent (SNP) | VAF 62/390 reads (16%) | catalogued as COSV53871652; called by muse, mutect2, varscan2
- WNK1 | c.2140-2243T>A | Intron (SNP) | VAF 49/297 reads (16%) | catalogued as COSV60035017; called by muse, mutect2, varscan2
